Gene-level copy-number profile of tumor specimen TCGA-L5-A4OM-01A from TCGA case TCGA-L5-A4OM, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 54.3 years (19,845 days).
Specimen TCGA-L5-A4OM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.fb3f937a-b585-432d-a41d-b3c37df687ba.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4OM-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dfcd5082-ed63-459e-b85e-85277cbaeb84

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 3; copy number 2: 12,972; copy number 3: 22,830; copy number 4: 16,111; copy number 5: 4,096; copy number 6: 2,075; copy number 7: 507; copy number 8: 1,051; copy number 10: 7; copy number 14: 40; copy number 17: 13; copy number 20: 28; copy number 25: 4; copy number 31: 6; copy number 35: 18; copy number 36: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A4OM-01A-11D-A25X-01): tumor purity 0.86, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:54,626,215–54,639,857, 2 genes: RPS15P5, ESRG.
- chr9:21,929,457–24,088,051, 26 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,703 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:99,802,699–112,031,649, 147 genes, copy number 8 (broad region; genes not listed).
- chr3:132,721,750–159,897,366, 452 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr3:159,988,835–159,996,019, 1 gene, copy number 7: IL12A.
- chr3:168,249,522–172,604,006, 82 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr3:176,113,702–192,917,856, 306 genes, copy number 7–8 (broad region; genes not listed).
- chr3:193,398,967–198,222,513, 171 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr5:50,396,192–50,443,248, 1 gene, copy number 7 (within-gene range 4–18): EMB.
- chr7:84,528,122–104,208,047, 424 genes, copy number 8–31 (broad region; genes not listed).
- chr11:68,870,664–72,290,688, 119 genes, copy number 14–36 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
